Somatic mutation profile of tumor specimen 0DTUIS from CCDI case PBCKFC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.0 years (3,273 days).
Specimen 0DTUIS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a95a8a58-0062-47d4-8d4c-42aa855eea58.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTUI3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ecd341a-9d05-49b7-9cc5-678c32b5780c

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Del 1, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DHX30 | c.333_360del p.Q112Sfs*7 (on ENST00000445061 / NM_138615.3; = p.Q73Sfs*7 on NM_014966.3) | Frame Shift Del (DEL) | VAF 58/375 reads (15%) | called by mutect2, pindel
- SSC5D | c.2871A>G p.K957= | Silent (SNP) | VAF 70/303 reads (23%) | called by muse, mutect2, varscan2
- CALM1 | c.178+97T>C | Intron (SNP) | VAF 44/151 reads (29%) | catalogued as rs752946983; called by muse, mutect2, varscan2
